Gene-level copy-number profile of tumor specimen ALCH-B1W9-TTP1-A from ALCHEMIST case ALCH-B1W9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.6 years (25,060 days).
Specimen ALCH-B1W9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2c1e7e2e-82c3-4bf9-89f7-9bcdbea0b8b2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1W9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,760 have no estimate.
https://portal.gdc.cancer.gov/files/4c2284ce-e779-40f9-a4df-a996d97cb797

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 646; copy number 1: 30,326; copy number 2: 23,896; copy number 3: 2,593; copy number 4: 417; copy number 5: 980; copy number 6: 3; copy number 42: 2.

Homozygous deletions (total copy number 0; autosomes only): 104 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,205,988–3,208,664, 1 gene (within-gene range 0–1): AL512383.1.
- chr9:135,702,185–135,795,508, 1 gene: KCNT1.
- chr10:131,772,398–131,795,277, 2 genes: LINC01164, AL450307.1.
- chr13:112,052,078–112,108,015, 5 genes: AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404.
- chr15:21,160,305–21,167,357, 1 gene: BMS1P16.
- chr22:47,115,838–50,801,309, 94 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,995 genes in 50 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–173,142,350, 1,063 genes, copy number 3–5 (broad region; genes not listed).
- chr1:198,156,994–209,857,565, 304 genes, copy number 3 (broad region; genes not listed).
- chr2:86,720,291–86,808,396, 2 genes, copy number 3 (within-gene range 1–3): RMND5A, CD8A.
- chr2:87,002,559–87,076,429, 4 genes, copy number 3–4: PLGLB1, ANAPC1P2, ANAPC1P2, AC092651.1.
- chr2:87,439,523–87,825,952, 11 genes, copy number 3 (within-gene range 3–4): LINC01943, CYTOR, AC133644.2, AC133644.1, PAFAH1B1P1, MIR4435-1, RPS14P5, ANAPC1P4, PLGLB2, RGPD2, MTATP8P2.
- chr2:97,081,098–97,100,874, 4 genes, copy number 4: GPAT2P2, FAHD2B, AC018892.3, RN7SL313P.
- chr2:97,281,356–97,304,151, 2 genes, copy number 6: AC159540.2, AC159540.1.
- chr2:97,492,663–97,589,965, 2 genes, copy number 42: ANKRD36B, AC017099.1.
- chr2:102,064,544–102,240,002, 3 genes, copy number 3: IL1R1, IL1R1-AS1, IL1RL2.
- chr3:4,490,891–5,069,044, 8 genes, copy number 3: ITPR1-DT, ITPR1, EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40, RNF10P1.
- chr3:117,544,205–118,810,836, 7 genes, copy number 3: RNU6-1200P, AC092691.1, AC092691.2, LINC02024, AC092691.3, AC068633.1, AC068633.2.
- chr3:152,243,828–152,496,813, 5 genes, copy number 3: MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1.
- chr4:4,048,211–4,248,223, 10 genes, copy number 3–5: AC116562.3, RPS3AP16, AC116562.2, AC116562.1, OR7E103P, UNC93B4, OR7E99P, OR7E43P, OTOP1, TMEM128.
- chr4:159,064,297–160,522,311, 8 genes, copy number 3: Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1, AC074344.2, LINC02233, AC093853.1.
- chr5:58,198–60,522,120, 829 genes, copy number 3–6 (within-gene range 2–6) (broad region; genes not listed).
- chr5:117,719,240–118,562,199, 5 genes, copy number 3 (within-gene range 2–3): AC114322.1, LINC02147, RPL7L1P4, LINC02208, LINC02148.
- chr6:11,173,452–11,515,710, 5 genes, copy number 3 (within-gene range 2–3): AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1.
- chr6:62,460,940–63,779,336, 19 genes, copy number 3 (within-gene range 2–3): DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr7:6,879,627–55,595,006, 750 genes, copy number 3–4 (broad region; genes not listed).
- chr7:68,640,798–73,865,890, 80 genes, copy number 3 (broad region; genes not listed).
- chr8:41,929,479–42,271,266, 9 genes, copy number 3: KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1.
- chr8:42,338,454–42,555,195, 8 genes, copy number 3: POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19.
- chr8:47,260,878–47,736,306, 6 genes, copy number 3: SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P.
- chr9:39,355,669–39,741,193, 12 genes, copy number 3: SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5.
- chr9:42,830,337–43,045,120, 8 genes, copy number 3: ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1.
- chr9:94,726,604–95,087,159, 7 genes, copy number 3 (within-gene range 2–3): AOPEP, MIR2278, AL807757.1, AL807757.2, AL353768.1, AL353768.2, MIR6081.
- chr10:14,061–689,668, 14 genes, copy number 3: AC215217.1, AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26.
- chr10:3,433,508–6,353,827, 71 genes, copy number 3 (broad region; genes not listed).
- chr10:97,356,358–97,433,444, 5 genes, copy number 3: RRP12, RPL34P20, AL355490.2, Y_RNA, PGAM1.
- chr11:55,262,155–55,298,270, 5 genes, copy number 3: TRIM48, AP005597.4, AP005597.3, AP005597.2, TRIM51HP.
- chr11:65,333,852–65,574,198, 25 genes, copy number 3: DPF2, TIGD3, AP000944.1, SLC25A45, FRMD8, NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1, LTBP3, AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B.
- chr11:67,398,181–67,506,263, 13 genes, copy number 3–4 (within-gene range 2–4): PPP1CA, TBC1D10C, CARNS1, RPS6KB2, RPS6KB2-AS1, PTPRCAP, CORO1B, GPR152, CABP4, TMEM134, AIP, MIR6752, PITPNM1.
- chr13:84,520,103–87,696,272, 20 genes, copy number 3: MTND4P1, MTND5P3, LINC00333, LINC00375, LINC00351, SLITRK6, AL162373.1, MOB1AP1, AL354994.1, DDX6P2, TXNL1P1, LINC00430, UBBP5, LIN28AP2, AL360267.2, AL360267.1, MIR4500HG, AL355578.1, MIR4500, SLITRK5.
- chr14:22,040,594–22,559,037, 103 genes, copy number 4 (broad region; genes not listed).
- chr14:30,874,514–37,596,059, 131 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr14:63,298,126–79,868,291, 400 genes, copy number 3–4 (broad region; genes not listed).
- chr15:21,980,277–22,095,857, 8 genes, copy number 4–5 (within-gene range 1–20): OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2.
- chr17:46,503,946–46,555,650, 3 genes, copy number 3: RDM1P2, LRRC37A2, RN7SL199P.
- chr20:50,310,711–50,479,991, 3 genes, copy number 3–4 (within-gene range 2–4): LINC01271, RN7SL636P, COX6CP2.
- chr20:53,567,065–54,269,542, 11 genes, copy number 3 (within-gene range 2–3): ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1.

Autosomal genes at a single copy (total copy number 1): 28,051. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
